Somatic mutation profile of tumor specimen TARGET-15-PARWPU-09A.2 (aliquot TARGET-15-PARWPU-09A.2-01D) from TARGET case TARGET-15-PARWPU, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,129 days).
Specimen TARGET-15-PARWPU-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21f36c81-72d8-4510-b048-d9d0420bab00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-PARWPU-14A (Bone Marrow Normal), aliquot TARGET-15-PARWPU-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b3b0007-93d3-49fb-86b6-b76045360748

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ELP4 | c.1167C>A p.D389E (on ENST00000350638; = p.D388E on NM_019040.5) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2
- UBR4 | c.13982G>T p.C4661F | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); called by muse, mutect2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 11/76 reads (14%) | catalogued as rs201441562; called by pindel, varscan2
- PCDHA9 | c.2394+43C>A | Intron (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100970133; called by muse, mutect2
